Surgical pathology report (de-identified scan), TCGA case TCGA-W5-AA33, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Mayo Clinic Rochester, specimen TCGA-W5-AA33-01A (Primary Tumor).

Male

Surgery Date:

DIAGNOSIS:

A. Gallbladder fossa, excision: Fibroadipose tissue with fat necrosis. No evidence of malignancy identified.

B. Lymph node, cystic duct, excision: A single lymph node is negative for neoplasm.

C. Liver, wedge excision: Poorly differentiated cholangiocarcinoma, is identified forming a single mass (4.9 x 3.9 x 2.2 cm). The tumor is confined to hepatic parenchyma. The tumor growth pattern is mass-forming. The hepatic parenchymal resection margin is involved by invasive carcinoma. The bile duct margin is negative for invasive carcinoma and carcinoma in situ. Major vessel invasion is absent. Microscopic invasion is absent. No regional lymph nodes identified. The non-neoplastic liver shows minimal steatosis (<5%). There is patchy mild portal lymphocytic infiltrate. Special stains were performed on paraffin-embedded tissue (Block C6) for trichrome, PAS, and iron. Trichrome shows portal fibrosis. No globules for alpha-1 antitrypsin are identified on PAS stain. The iron stain shows trace hemosiderosis.

D. Liver, segment 5, 6, new margin, wedge resection: Fibroadipose tissue with fat necrosis. No evidence of malignancy identified.

ICD-O-3

Cholangiocarcinoma 8160/3

Site: Intrahepatic bile duct C22.1

W 3/8/14

Source: NCI Genomic Data Commons file 5fcb7a75-4c2a-470c-b85b-058a6c530f6d (TCGA-W5-AA33.FAB26B40-D86E-4937-9D4D-2473D2AA838F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).